Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A814, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A814-01A (Primary Tumor).

ICD-O-3
Paraganglioma, extra-adrenal NOS
86931
Site: Retroperitoneum C48.0
QW10/17/13

Date receiving:

Right adrenalectomy, resection of a paraganglioma and an periaortic-pericave lymph node

Clinical history Headache and hypertension known since at the age of . Right abdominal pain in . At CT scan, two hypervascular retroperitoneal nodules. Combination of headache, sweating and palpitations and hypertension lead to metanephrines measurements which were high. Further imaging and surgery are postponed due to pregnancy. Preeclampsia justifying a cesarean. Birth of a healthy child (2870 g). In very high metanephrines levels; chromogranin 750 $\mu\text{mol/l}$; I-MIBG scintigraphy positive on the upper pole of the right kidney. Ambulatory blood pressure monitoring values to 138/89 mmHg during the day. Body mass index 39.8 kg / m^2 . Diabetes revealed during pregnancy. Plasma glucose and HbA1c to 7.2 mm/l and 7.6%, respectively.

No left ventricular hypertrophy. Normal renal function and physiological microalbuminuria. Metanephrines on hold.

On CTscan, two lesions of the right abdomen, 1. right adrenal lesion of 31 mm; 2. a mass located 2 cm above the lower pole of the first lesion and in front of the third duodenum measuring 47 mm long axis. DOPA-PET reveals equally the both lesions.

Macroscopy

- Right adrenalectomy: resection of 34 g, 28 x 3.5 x 2 cm. After cutting, a buff-beige tumor partially kystic of 3.5 x 3 x 2 cm. Extra-tumoral adrenal does not contain micro-nodulation.
- Inter-aorto-caval paraganglioma: resection of 36 g 4 x 5 x 2 cm. Buff-beige aspect redesigned by the bleeding. The lesion is encapsulated.
- Inter-aorto-caval lymph node 0.5 cm

Microscopy

The adrenal tumor is composed by 40% of small cells, suggesting the cells of the adrenal medulla. Cellularity is high. In these areas, the population appears monotonous. These elements are arranged in nests zellballen type, but regularly take a fusiform arrangement (30%).

The nuclear atypia are marked

The interstitial tissue is here reduced to its capillary vascular component. Elsewhere, it forms fibrous bands containing vessels with their own wall. Hemorrhagic suffusions are visible with siderophages. Proliferation invades capsule, erodes largely without pass it. It does not invade the peri adrenal fat.

At IHC, tumor elements are chromogranin and synaptophysin positive. PS 100 marks rarely sustentacular elements.

The extra-tumoral adrenal showed no medullary hyperplasia. There are no glomerulosa hyperplasia or nodulation from fasciculata.

The periaortic-pericave paraganglioma is constituted by small pheochromocytomic cells for the most part, arranged in "zellballen" (40%). Elsewhere, the organization is diffuse or in large nests. Large hemorrhagic reorganizations are visible. Proliferation crosses the capsule and the tumor invades perirenal fat. It also invades a peritumoral lymph node. No vascular invasion has been seen.

At IHC, tumor elements have the same phenotype as described above. The network of sustentacular cells appears reduced in diffuse fusiform areas. Chromogranin and synaptophysin mark the cells of the lymph node. They also mark the inter-aortico-caval lymph node enclosed in fibrosis.

CONCLUSION

Right adrenalectomy. Resection of a periaortic-pericave paraganglioma. Inter-aortico-caval lymph node. Adrenal tumor of 3.5 cm, PASS score = 6 (cellularity=2; fusiform aspect=2; capsular invasion =2; nuclear pleomorphism=1). Periaortic-pericave paraganglioma of 5 cm with capsular invasion, invasion of the adjacent fat and lymph node extension at contact. Tumoral extension to the inter-node aorto-caval lymph node. The prognosis of these both chromaffin tumors appears reserved.

Translated on from the original pathological report evaluated on

Criteria	W 9/24/13	Yes	No
Recr Malignancy History			✓

Source: NCI Genomic Data Commons file ee4b2f79-3f6b-494e-aec5-37d1c98cab13 (TCGA-WB-A814.D7FF3797-73AC-4850-BA47-5F81342F036B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).